Somatic mutation profile of tumor specimen C3L-06984-55 (aliquot CPT0408880002) from CPTAC case C3L-06984, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 36.9 years (13,469 days).
Specimen C3L-06984-55: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60520e71-494d-4569-98a5-0e40c5276c94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06984-50 (Buccal Cell Normal), aliquot CPT0408850001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dab102cf-59d8-4dea-841e-3ebc549ce54c

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Frame Shift Ins 2, Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121918459, CM013416, COSV61007856; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCCAG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 18/49 reads (37%) | catalogued as COSV51544444, COSV51555499, COSV51560925, COSV51570713; called by mutect2, pindel, varscan2
- SLC22A2 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs758136736; called by muse, mutect2, varscan2
- WT1 | c.1102dup p.R368Pfs*5 | Frame Shift Ins (INS) | VAF 166/414 reads (40%) | catalogued as COSV60065714, COSV60066671, COSV60067526, COSV60073219, COSV60075996, COSV60077962, COSV60079089, COSV60085405; called by mutect2, pindel, varscan2
- COBLL1 | c.1665A>G p.K555= (on ENST00000392717; = p.K517= on NM_014900.5) | Silent (SNP) | VAF 27/79 reads (34%) | called by mutect2, varscan2
- SLC18A2 | c.471C>G p.G157= | Silent (SNP) | VAF 46/130 reads (35%) | called by muse, mutect2, varscan2
- IFT74 | c.121-1358T>A | Intron (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
